Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0M2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0M2-01A (Primary Tumor).

100-0-3

adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 *hw* 5/3/11

FINAL DIAGNOSIS:

PART 1: PELVIC LYMPH NODES, LEFT, EXCISION -

THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/3).

PART 2: PERIAORTIC LYMPH NODES, LEFT, EXCISION -

- A. BENIGN ADIPOSE TISSUE.
- B. NO LYMPHOID TISSUE IS IDENTIFIED.
- C. ENTIRE SPECIMEN SUBMITTED FOR HISTOLOGIC EVALUATION.

PART 3: PELVIC LYMPH NODES, RIGHT, EXCISION -

FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/5).

PART 4: PERIAORTIC LYMPH NODES, RIGHT, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 5: UTERUS, CERVIX, BILATERAL OVARIES AND FALLOPIAN TUBES, LAPAROSCOPIC ABDOMINAL HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY -

- A. ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, FIGO GRADE 2, NUCLEAR GRADE 2.
- B. THE TUMOR INVADDES 59% OF THE MYOMETRIAL THICKNESS (1.0 CM INVASION OF 1.7 CM THICK MYOMETRIUM).
- C. THE TUMOR INVOLVES APPROXIMATELY 50% OF THE ENDOMETRIAL CAVITY SURFACE.
- D. CERVIX WITH BENIGN TUNNEL CLUSTERS AND CHRONIC CERVICITIS, NEGATIVE FOR CARCINOMA.
- E. LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED.
- F. THE BACKGROUND ENDOMETRIUM SHOWS COMPLEX ATYPICAL HYPERPLASIA AND POLYPS IN THE LOWER UTERINE SEGMENT.
- G. THE MYOMETRIUM SHOWS LEIOMYOMATA UTERI (0.5-2.5 CM).
- H. BILATERAL OVARIES ARE UNREMARKABLE.
- I. BILATERAL FALLOPIAN TUBES ARE UNREMARKABLE.

COMMENT:

Companion pelvic wash [REDACTED] is negative for malignant cells.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE:

Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE:

Moderately differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 4 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 25 %, Posterior endomyometrium: 90 %

DEPTH OF INVASION**:

Greater than 1/2 thickness of myometrium

ANGIOLYMPHATIC INVASION:

Yes

PRE-NEOPLASTIC CONDITIONS:

Complex endometrial hyperplasia with atypia (epithelial, smooth muscle, others), Leiomyoma

OTHER:

Number of lymph nodes positive: 0

LYMPH NODES POSITIVE:

Total number of lymph nodes examined: 9

LYMPH NODES EXAMINED:

T STAGE, PATHOLOGIC:

pT1c

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IC

Diagnosis Discrepancy		hw
Primary Tumor Site Discrepancy		hw
HIPAA Discrepancy		hw
Prior Malignancy History		hw
Dual/Synchronous Primary Noted		hw

Source: NCI Genomic Data Commons file 0d897ec8-75d3-487e-afe1-425cf5bb325a (TCGA-BG-A0M2.A0087300-81E9-4733-8497-95E0F95575B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).